Somatic mutation profile of tumor specimen MP2PRT-PASKHD-TMP1-A (aliquot MP2PRT-PASKHD-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASKHD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,466 days).
Specimen MP2PRT-PASKHD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b65d0238-cc42-47b9-a46e-e732e00227ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKHD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKHD-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f11dcb9-a976-4960-9e1d-7126f43e94e3

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/167 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTAGE15 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 197/298 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV69481819; called by muse, mutect2, varscan2
- NOS1 | c.3329C>T p.T1110M | Missense Mutation (SNP) | VAF 195/515 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs562794276; called by muse, mutect2, varscan2
- TXNDC2 | c.1519G>A p.A507T (on ENST00000306084 / NM_001098529.2; = p.A440T on NM_032243.6) | Missense Mutation (SNP) | VAF 187/676 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs771795630, COSV60155809; called by muse, mutect2, varscan2
- WSCD1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 378/1212 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs750491123; called by muse, mutect2, varscan2
- L1TD1 | c.1218_1250del p.P410_E420del | In Frame Del (DEL) | VAF 12/256 reads (5%) | called by mutect2, pindel
- ZNF142 | c.3905C>G p.A1302G (on ENST00000411696 / NM_001379660.1; = p.A1102G on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/594 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FCHSD2 | c.273C>T p.L91= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs199892054, COSV60812181; called by muse, mutect2, varscan2
- GSTA5 | c.516G>T p.S172= | Silent (SNP) | VAF 80/200 reads (40%) | catalogued as COSV99489717; called by muse, mutect2, varscan2
- LRRC49 | c.57C>T p.C19= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs562967881; called by muse, mutect2, varscan2
